Somatic mutation profile of tumor specimen TCGA-B6-A0WV-01A (aliquot TCGA-B6-A0WV-01A-11D-A10G-09) from TCGA case TCGA-B6-A0WV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.9 years (24,803 days).
Specimen TCGA-B6-A0WV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bca245d6-09df-48d0-9845-b31a7b4ebf11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0WV-10A (Blood Derived Normal), aliquot TCGA-B6-A0WV-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c508f671-d511-4e04-a955-48e8e6268396

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Ins 3, In Frame Del 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN3L | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 25/412 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV101019293; called by muse, mutect2
- CCDC14 | c.679C>T p.P227S (on ENST00000488653; = p.P179S on NM_022757.5) | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.046); catalogued as rs1481789035, COSV59945710; called by muse, mutect2, varscan2
- ERO1A | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.173); catalogued as rs989140446, COSV67471532; called by muse, mutect2, varscan2
- FAM78A | c.598A>C p.T200P | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99908425; called by muse, mutect2, varscan2
- FRG1 | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289900718, COSV57003938; called by mutect2, varscan2
- GATA3 | c.999dup p.G334Wfs*18 | Frame Shift Ins (INS) | VAF 69/336 reads (21%) | catalogued as COSV60517073; called by mutect2, pindel, varscan2
- GTPBP2 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 73/105 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61076683; called by muse, mutect2, varscan2
- HERC6 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV52031601; called by muse, mutect2, varscan2
- KCND1 | c.221_223del p.F74del | In Frame Del (DEL) | VAF 31/98 reads (32%) | catalogued as rs1557058703; called by pindel, varscan2
- KCNJ15 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765815153, COSV60811301; called by muse, mutect2, varscan2
- KLRC1 | c.566T>C p.M189T | Missense Mutation (SNP) | VAF 165/421 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV61725432; called by muse, mutect2, varscan2
- NALCN | c.2482G>C p.E828Q | Missense Mutation (SNP) | VAF 331/482 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51945673; called by muse, mutect2, varscan2
- NRAP | c.2885G>A p.R962H (on ENST00000359988 / NM_001322945.2; = p.R927H on NM_006175.4) | Missense Mutation (SNP) | VAF 165/287 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as rs767691664, COSV63491550; called by muse, mutect2
- OR5J2 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 153/369 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1331847459, COSV56622074, COSV56622346; called by muse, mutect2, varscan2
- PHLDB2 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV67312986; called by muse, mutect2, varscan2
- PIWIL4 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV54410311; called by muse, mutect2, varscan2
- SERPIND1 | c.1124C>G p.P375R | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as rs778720255, COSV53139424; called by muse, mutect2, varscan2
- SMAD9 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 70/97 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.271); catalogued as rs1049883784, COSV63204845; called by muse, mutect2, varscan2
- STK38L | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 186/433 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV66522036; called by muse, mutect2, varscan2
- TPCN1 | c.1940A>T p.N647I | Missense Mutation (SNP) | VAF 137/346 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59236621; called by muse, mutect2, varscan2
- UBE2A | c.167del p.T56Kfs*2 | Frame Shift Del (DEL) | VAF 106/287 reads (37%) | catalogued as COSV60636854; called by mutect2, pindel, varscan2
- VPS54 | c.1789A>G p.N597D | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs368681209; called by muse, mutect2, varscan2
- VSIG8 | c.607_609del p.S203del | In Frame Del (DEL) | VAF 40/192 reads (21%) | catalogued as COSV63653194; called by mutect2, pindel, varscan2
- CCDC159 | c.527dup p.N176Kfs*25 | Frame Shift Ins (INS) | VAF 101/313 reads (32%) | called by mutect2, pindel, varscan2
- KMT2C | c.5079dup p.V1694Cfs*7 | Frame Shift Ins (INS) | VAF 130/476 reads (27%) | called by mutect2, pindel, varscan2
- ZNF292 | c.1109_1112del p.S370Ffs*21 | Frame Shift Del (DEL) | VAF 152/242 reads (63%) | called by mutect2, pindel, varscan2
- CDIPT | c.78C>T p.F26= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as COSV99570101; called by muse, mutect2
- DDX31 | c.1692G>A p.Q564= | Silent (SNP) | VAF 4/103 reads (4%) | catalogued as COSV60135946; called by muse, mutect2
- HADHA | c.1005A>G p.E335= | Silent (SNP) | VAF 108/363 reads (30%) | catalogued as COSV66107903; called by muse, mutect2, varscan2
- HELZ | c.2463T>G p.G821= | Silent (SNP) | VAF 192/466 reads (41%) | catalogued as COSV100698474; called by muse, varscan2
- KCNJ16 | c.531G>A p.K177= | Silent (SNP) | VAF 63/220 reads (29%) | catalogued as rs780231296, COSV52254833; called by muse, mutect2, varscan2
- PHACTR1 | c.720A>T p.L240= | Silent (SNP) | VAF 86/131 reads (66%) | catalogued as COSV60671762; called by muse, mutect2, varscan2
- PTPRB | c.5781A>G p.K1927= | Silent (SNP) | VAF 185/525 reads (35%) | catalogued as COSV54245011; called by muse, mutect2, varscan2
- VPS13D | c.2028A>G p.Q676= | Silent (SNP) | VAF 100/235 reads (43%) | catalogued as rs747363459, COSV62531089; called by muse, mutect2, varscan2
